Somatic mutation profile of tumor specimen 0DAGOZ from CCDI case PBBKAF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.1 years (2,590 days).
Specimen 0DAGOZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0999223d-07b7-43a6-bfa2-be7b3911223c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAGOV (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2944981-4388-4d45-927e-465fc57953f0

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABRAXAS2 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1171693046, COSV53715841, COSV53718164; called by muse, mutect2, varscan2
- LAMC2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs201614830, COSV99917157; called by muse, mutect2, varscan2
- NBPF12 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.022); called by mutect2, varscan2
- PECR | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- RPA3 | c.10A>T p.M4L | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
